Somatic mutation profile of tumor specimen TCGA-CN-6019-01A (aliquot TCGA-CN-6019-01A-11D-1683-08) from TCGA case TCGA-CN-6019, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 61.6 years (22,485 days).
Specimen TCGA-CN-6019-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c1896146-cf51-4878-b53b-54e85554defe.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CN-6019-10A (Blood Derived Normal), aliquot TCGA-CN-6019-10A-01D-1683-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/18c789d6-6ba3-4e70-bc33-ade2895c0ecf

The open-access MAF lists 137 somatic variants for this specimen: 107 protein-altering or splice-affecting, 25 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 93, Silent 25, Nonsense Mutation 7, Splice Site 3, Intron 2, Frame Shift Del 2, RNA 2, Frame Shift Ins 1, In Frame Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C8orf37 | c.529C>T p.R177W | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs387907136, CM120200, COSV99713098; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.994-1G>T p.X332_splice | Splice Site (SNP) | VAF 5/23 reads (22%) | hotspot (GDC flag); catalogued as CS002470, CS033842, CS103209, COSV52668116, COSV52746625, COSV52766192; called by muse, mutect2
- ABCA6 | c.1603G>T p.E535* | Nonsense Mutation (SNP) | VAF 17/107 reads (16%) | catalogued as COSV99446125; called by muse, mutect2, varscan2
- ABHD11 | c.358A>T p.S120C | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.359); catalogued as COSV99766743; called by muse, varscan2
- ADAMTS12 | c.3958G>A p.G1320R | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs772207271, COSV61263569; called by muse, mutect2, varscan2
- ARHGAP5 | c.3718C>T p.Q1240* | Nonsense Mutation (SNP) | VAF 9/47 reads (19%) | catalogued as COSV100565123; called by muse, mutect2
- ARPP21 | c.461T>A p.I154N | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV51794305, COSV99491478; called by muse, mutect2, varscan2
- ATP9B | c.539A>G p.Y180C | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.984); catalogued as COSV100303199; called by muse, mutect2, varscan2
- C11orf53 | c.679G>A p.G227R | Missense Mutation (SNP) | VAF 27/140 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.929); catalogued as COSV54721287; called by muse, mutect2, varscan2
- C2CD2 | c.894G>T p.R298S | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV100298062; called by muse, mutect2
- CD163L1 | c.2918A>T p.E973V | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58016820; called by muse, mutect2, varscan2
- CELSR2 | c.6904G>T p.V2302F | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.645); catalogued as COSV99603399; called by muse, mutect2, varscan2
- CFAP61 | c.1351G>A p.D451N | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV99844018; called by muse, mutect2, varscan2
- CHIC2 | c.275G>T p.C92F | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.999); catalogued as COSV99816023; called by muse, varscan2
- CLDN6 | c.593C>T p.A198V | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.96); catalogued as COSV100172102; called by muse, mutect2, varscan2
- CLVS1 | c.408C>A p.Y136* | Nonsense Mutation (SNP) | VAF 10/45 reads (22%) | catalogued as COSV57981019, COSV57981660; called by muse, mutect2, varscan2
- COL22A1 | c.3523G>A p.A1175T | Missense Mutation (SNP) | VAF 35/221 reads (16%) | SIFT tolerated (0.64); PolyPhen benign (0.006); catalogued as rs199555238, COSV100277278; called by muse, mutect2, varscan2
- COL6A6 | c.766G>T p.V256L | Missense Mutation (SNP) | VAF 33/225 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.072); catalogued as COSV100650072; called by muse, mutect2, varscan2
- COL6A6 | c.2365G>C p.D789H | Missense Mutation (SNP) | VAF 10/110 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.622); catalogued as COSV100650073; called by muse, mutect2
- CREB3L2 | c.1370C>T p.S457F | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.084); catalogued as COSV100381733; called by muse, mutect2, varscan2
- CSMD3 | c.32C>G p.A11G | Missense Mutation (SNP) | VAF 21/109 reads (19%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.172); catalogued as COSV99829417; called by muse, mutect2, varscan2
- CUL3 | c.1561A>T p.K521* | Nonsense Mutation (SNP) | VAF 22/137 reads (16%) | catalogued as COSV100023988; called by muse, mutect2, varscan2
- DLGAP4 | c.695G>A p.R232H | Missense Mutation (SNP) | VAF 11/124 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs141000110; called by muse, mutect2
- DNAH10 | c.6348G>T p.L2116F (on ENST00000409039; = p.L2055F on NM_207437.3) | Missense Mutation (SNP) | VAF 7/63 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101292122; called by muse, mutect2, varscan2
- DNAH17 | c.2462G>T p.R821I | Missense Mutation (SNP) | VAF 31/215 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.802); catalogued as COSV101101800; called by muse, mutect2, varscan2
- DNMBP | c.88G>A p.E30K | Missense Mutation (SNP) | VAF 35/145 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100143396; called by muse, mutect2, varscan2
- DUS2 | c.1352G>A p.R451Q | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as rs1486080979, COSV100732449; called by muse, mutect2, varscan2
- ENPP2 | c.1541G>C p.C514S (on ENST00000075322 / NM_001040092.3; = p.C566S on NM_006209.5) | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1409173361, COSV50012682, COSV99307912; called by muse, mutect2
- EPB41L2 | c.2122G>A p.E708K | Missense Mutation (SNP) | VAF 8/85 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.26); catalogued as COSV100440429, COSV61357321; called by muse, mutect2
- EPB41L3 | c.1438G>A p.E480K | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.165); catalogued as rs780187679, COSV59450551; called by muse, mutect2, varscan2
- EPHA6 | c.139G>T p.G47W | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.626); catalogued as COSV101061460; called by muse, mutect2
- EYA4 | c.656G>T p.C219F | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV100765546, COSV100766410; called by muse, mutect2, varscan2
- EYS | c.1289G>T p.G430V | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV100676075; called by muse, mutect2
- EYS | c.1288G>T p.G430* | Nonsense Mutation (SNP) | VAF 6/59 reads (10%) | catalogued as COSV100676079; called by muse, mutect2
- FABP7 | c.232G>T p.D78Y | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100737913; called by muse, mutect2
- FBXL7 | c.463A>T p.R155W | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as COSV100309408; called by muse, mutect2
- FGA | c.2456G>C p.G819A | Missense Mutation (SNP) | VAF 27/122 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100120209; called by muse, mutect2, varscan2
- FOXG1 | c.1042A>C p.N348H | Missense Mutation (SNP) | VAF 21/155 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.916); catalogued as COSV100486637; called by muse, mutect2, varscan2
- FSTL5 | c.566C>A p.A189E | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0.231); catalogued as COSV60180675, COSV60216155; called by muse, mutect2, varscan2
- FZD1 | c.1463G>T p.R488L | Missense Mutation (SNP) | VAF 35/227 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.839); catalogued as COSV55309879, COSV99842451; called by muse, mutect2, varscan2
- GABRG1 | c.1138C>A p.P380T | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0.015); catalogued as COSV99777651; called by muse, mutect2, varscan2
- GLDN | c.1618T>C p.Y540H | Missense Mutation (SNP) | VAF 19/131 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.863); catalogued as rs777551159, COSV100117586; called by muse, mutect2, varscan2
- GPR149 | c.1498A>G p.I500V | Missense Mutation (SNP) | VAF 40/252 reads (16%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs1303931230, COSV101078243; called by muse, mutect2, varscan2
- HSD17B4 | c.355G>A p.D119N (on ENST00000414835 / NM_001199291.3; = p.D94N on NM_000414.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99819648, COSV99820295; called by muse, mutect2, varscan2
- INVS | c.1933C>T p.P645S | Missense Mutation (SNP) | VAF 10/53 reads (19%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as rs1362558669, COSV99317295; called by muse, mutect2, varscan2
- KCNIP4 | c.262C>T p.Q88* | Nonsense Mutation (SNP) | VAF 17/101 reads (17%) | catalogued as COSV100749234; called by muse, mutect2, varscan2
- KIF9 | c.2083C>T p.R695C (on ENST00000265529 / NM_001377474.1; = p.R630C on NM_022342.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs752628802, COSV99646538; called by muse, mutect2, varscan2
- LY9 | c.325A>T p.I109F | Missense Mutation (SNP) | VAF 23/100 reads (23%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.879); catalogued as rs765416566, COSV99626456; called by muse, mutect2, varscan2
- MACROD2 | c.445G>T p.A149S | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.996); catalogued as COSV54002276; called by muse, mutect2, varscan2
- MUC5B | c.5858C>T p.A1953V | Missense Mutation (SNP) | VAF 27/126 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV101500173, COSV71594323; called by muse, mutect2, varscan2
- MYCBPAP | c.1648G>T p.A550S | Missense Mutation (SNP) | VAF 19/105 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as COSV100087921; called by muse, mutect2, varscan2
- MYH2 | c.3185A>T p.E1062V | Missense Mutation (SNP) | VAF 9/77 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV99819674; called by muse, mutect2, varscan2
- NCAM2 | c.2339C>A p.T780N | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.076); catalogued as COSV99522209; called by muse, mutect2, varscan2
- NCOA2 | c.4180A>T p.M1394L | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.041); catalogued as COSV99144743; called by muse, mutect2, varscan2
- NCOA3 | c.277G>A p.D93N | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.823); catalogued as COSV100507336; called by muse, mutect2, varscan2
- NEK5 | c.515C>A p.S172Y | Missense Mutation (SNP) | VAF 27/88 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100839174; called by muse, mutect2, varscan2
- NF1 | c.1642G>T p.A548S | Missense Mutation (SNP) | VAF 4/51 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100646409; called by muse, mutect2
- NFE2L2 | c.95T>G p.V32G | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.115); catalogued as COSV67960747, COSV67960841; called by muse, mutect2, varscan2
- NUP88 | c.1917-2A>G p.X639_splice | Splice Site (SNP) | VAF 11/42 reads (26%) | catalogued as COSV99336441; called by muse, mutect2, varscan2
- NXPE1 | c.1259C>G p.P420R (on ENST00000424269; = p.P278R on NM_152315.5) | Missense Mutation (SNP) | VAF 26/122 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs975762989, COSV52630071, COSV99320142; called by muse, mutect2, varscan2
- OLFM3 | c.1031T>C p.F344S (on ENST00000338858 / NM_001288821.1; = p.F324S on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.135); catalogued as COSV100129113; called by muse, mutect2, varscan2
- OR5M11 | c.797C>A p.T266N | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.013); catalogued as COSV101602027; called by muse, mutect2
- PAX4 | c.788T>C p.V263A | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.012); catalogued as rs773621758, COSV100490040; called by muse, mutect2, varscan2
- PDE11A | c.371G>A p.S124N | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV99611354; called by muse, mutect2, varscan2
- PHACTR3 | c.385G>A p.D129N | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs201601907, COSV63031678; called by muse, mutect2, varscan2
- PKHD1 | c.1438C>A p.P480T | Missense Mutation (SNP) | VAF 30/129 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100582137; called by muse, mutect2, varscan2
- PLEKHG1 | c.1940G>C p.G647A | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.612); catalogued as COSV100651544; called by muse, mutect2, varscan2
- PPP1R10 | c.625C>T p.R209C | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1225543811, COSV64739435; called by muse, mutect2, varscan2
- PRDM5 | c.395A>T p.E132V | Missense Mutation (SNP) | VAF 29/129 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.296); catalogued as COSV99310179; called by muse, mutect2, varscan2
- RACGAP1 | c.1463A>C p.H488P | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.082); catalogued as COSV100407628; called by muse, mutect2, varscan2
- RASGRF1 | c.409G>A p.E137K | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs150686548; called by mutect2, varscan2
- RELN | c.4739C>G p.P1580R | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100633006, COSV59024786; called by muse, mutect2, varscan2
- RFTN1 | c.277G>A p.E93K | Missense Mutation (SNP) | VAF 28/122 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.267); catalogued as COSV61920285; called by muse, mutect2, varscan2
- RNF213 | c.6526C>A p.Q2176K | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT tolerated (0.18); PolyPhen benign (0.193); catalogued as COSV100300082, COSV100301691; called by muse, mutect2, varscan2
- RPL36 | c.198C>A p.D66E | Missense Mutation (SNP) | VAF 14/95 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.211); catalogued as COSV100028511; called by muse, mutect2, varscan2
- SLC16A10 | c.238T>C p.C80R | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100785622; called by muse, mutect2, varscan2
- SPATC1 | c.635A>T p.N212I | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as COSV101084846; called by muse, mutect2
- SPG11 | c.3412A>G p.S1138G | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs377351819; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SPOPL | c.571G>T p.G191C | Missense Mutation (SNP) | VAF 28/134 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99699383; called by muse, varscan2
- SPOPL | c.572G>T p.G191V | Missense Mutation (SNP) | VAF 28/138 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV99699385; called by muse, varscan2
- STK10 | c.1591C>T p.R531C | Missense Mutation (SNP) | VAF 10/234 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51574174, COSV51577312; called by muse, mutect2
- SYNE1 | c.23403C>A p.S7801R (on ENST00000367255 / NM_182961.4; = p.S7730R on NM_033071.3) | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99557881; called by muse, mutect2, varscan2
- SYNE1 | c.22673T>A p.I7558N (on ENST00000367255 / NM_182961.4; = p.I7487N on NM_033071.3) | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99557884; called by mutect2, varscan2
- TANC1 | c.1542C>G p.Y514* | Nonsense Mutation (SNP) | VAF 53/401 reads (13%) | catalogued as COSV99713398; called by muse, mutect2, varscan2
- TEKT5 | c.496A>G p.N166D | Missense Mutation (SNP) | VAF 52/325 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.027); catalogued as COSV99295940; called by muse, mutect2, varscan2
- TIMD4 | c.918G>T p.M306I | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as COSV50854235, COSV99192544; called by muse, mutect2, varscan2
- TLN1 | c.4565A>T p.K1522M | Missense Mutation (SNP) | VAF 74/212 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV100147509; called by muse, mutect2, varscan2
- TTLL4 | c.1703A>G p.E568G | Missense Mutation (SNP) | VAF 32/138 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as COSV99293173; called by muse, mutect2, varscan2
- TTN | c.5981C>T p.S1994L (on ENST00000591111; = p.S1948L on NM_003319.4) | Missense Mutation (SNP) | VAF 22/157 reads (14%) | PolyPhen possibly damaging (0.683); catalogued as rs758483877, COSV59887888; called by muse, mutect2, varscan2
- UPF1 | c.1672A>G p.K558E (on ENST00000599848 / NM_001297549.2; = p.K547E on NM_002911.4) | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.337); catalogued as COSV99439107; called by muse, mutect2, varscan2
- USH2A | c.10947G>C p.Q3649H | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.766); catalogued as rs776022618, COSV100231883; called by muse, mutect2
- USH2A | c.3462A>T p.L1154F | Missense Mutation (SNP) | VAF 18/122 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100231888, COSV56381793; called by muse, mutect2, varscan2
- VPS50 | c.881A>T p.E294V | Missense Mutation (SNP) | VAF 31/125 reads (25%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.951); catalogued as COSV99297938; called by muse, mutect2, varscan2
- WNK4 | c.2150C>A p.A717D | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.219); catalogued as COSV99889815; called by muse, mutect2, varscan2
- ZGRF1 | c.5507A>C p.D1836A | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV101500584, COSV71393223; called by muse, mutect2
- ZIC4 | c.715G>A p.E239K | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.316); catalogued as COSV101267892; called by muse, mutect2, varscan2
- ZIC4 | c.347T>A p.F116Y | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); catalogued as COSV101267894; called by muse, mutect2, varscan2
- ZNF254 | c.732C>A p.N244K | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.062); catalogued as COSV100741557; called by muse, mutect2, varscan2
- ZNF415 | c.1493G>T p.C498F | Missense Mutation (SNP) | VAF 28/207 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99701399, COSV99701478; called by muse, mutect2, varscan2
- ZNF646 | c.139C>G p.P47A | Missense Mutation (SNP) | VAF 14/104 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as COSV100336514; called by muse, varscan2
- ZNF91 | c.890A>T p.E297V | Missense Mutation (SNP) | VAF 20/112 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.02); catalogued as COSV100322443; called by muse, mutect2, varscan2
- CDKN2A | c.52_63del p.T18_A21del | In Frame Del (DEL) | VAF 6/34 reads (18%) | called by mutect2, varscan2
- CNTN6 | c.785_786dup p.R263Efs*91 | Frame Shift Ins (INS) | VAF 18/132 reads (14%) | called by mutect2, pindel, varscan2
- HMGXB4 | c.1692_1693del p.A565Pfs*13 | Frame Shift Del (DEL) | VAF 10/82 reads (12%) | called by pindel, varscan2
- SEMA6D | c.966-1G>T p.X322_splice | Splice Site (SNP) | VAF 5/84 reads (6%) | called by muse, mutect2
- TPTE | c.1115G>A p.R372K (on ENST00000618007 / NM_199261.4; = p.R354K on NM_199259.4) | Missense Mutation (SNP) | VAF 20/172 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.089); called by muse, mutect2
- WDR72 | c.3099del p.W1033* | Frame Shift Del (DEL) | VAF 32/246 reads (13%) | called by mutect2, pindel, varscan2
- ABCA6 | c.3036G>A p.G1012= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as COSV99446124; called by muse, mutect2, varscan2
- C7orf33 | c.15T>G p.V5= | Silent (SNP) | VAF 10/51 reads (20%) | catalogued as COSV100188747; called by muse, varscan2
- CHRNB1 | c.414C>T p.S138= | Silent (SNP) | VAF 10/49 reads (20%) | catalogued as rs759413080, COSV99548201; called by mutect2, varscan2
- COL1A2 | c.3942A>G p.V1314= | Silent (SNP) | VAF 7/75 reads (9%) | catalogued as COSV99799092; called by muse, mutect2, varscan2
- DNMT3A | c.2229C>T p.P743= | Silent (SNP) | VAF 24/114 reads (21%) | catalogued as COSV99261027; called by muse, mutect2, varscan2
- FERMT2 | c.951T>C p.F317= | Silent (SNP) | VAF 31/120 reads (26%) | catalogued as COSV100448814; called by muse, mutect2, varscan2
- KIAA1210 | c.3354G>T p.L1118= | Silent (SNP) | VAF 6/96 reads (6%) | catalogued as COSV101274015; called by muse, mutect2
- KIAA1549 | c.339G>A p.P113= | Silent (SNP) | VAF 12/116 reads (10%) | catalogued as rs1177918017, COSV54306137; called by muse, mutect2, varscan2
- LATS2 | c.1179C>T p.H393= | Silent (SNP) | VAF 7/15 reads (47%) | catalogued as rs1027131519, COSV66874363; called by muse, mutect2, varscan2
- LILRA1 | c.162G>A p.E54= | Silent (SNP) | VAF 16/118 reads (14%) | catalogued as rs1379248257, COSV99251817; called by muse, varscan2
- MED13L | c.2148T>C p.Y716= | Silent (SNP) | VAF 26/166 reads (16%) | catalogued as COSV99928300; called by muse, mutect2, varscan2
- MLXIPL | c.2415C>T p.Y805= | Silent (SNP) | VAF 15/79 reads (19%) | catalogued as COSV100515247; called by muse, mutect2, varscan2
- NFE2L3 | c.1833T>C p.C611= | Silent (SNP) | VAF 10/72 reads (14%) | catalogued as COSV99283588; called by muse, mutect2, varscan2
- PHF3 | c.3684A>G p.V1228= | Silent (SNP) | VAF 33/146 reads (23%) | catalogued as rs541787048, COSV100013077; called by muse, mutect2, varscan2
- PTBP2 | c.1159C>T p.L387= (on ENST00000426398 / NM_001300986.2; = p.L379= on NM_021190.4) | Silent (SNP) | VAF 6/68 reads (9%) | catalogued as COSV100930191; called by muse, mutect2
- RPLP0 | c.924C>T p.D308= | Silent (SNP) | VAF 10/72 reads (14%) | catalogued as rs375808013; called by muse, mutect2, varscan2
- SPOPL | c.510A>C p.I170= | Silent (SNP) | VAF 15/98 reads (15%) | catalogued as COSV99699381; called by muse, varscan2
- ST6GAL2 | c.459C>T p.P153= | Silent (SNP) | VAF 17/318 reads (5%) | catalogued as rs142520495, COSV64529387; called by muse, mutect2
- STOX2 | c.2634C>T p.N878= | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as COSV100408532; called by muse, mutect2, varscan2
- TNN | c.249C>T p.N83= | Silent (SNP) | VAF 17/73 reads (23%) | catalogued as COSV99511505; called by muse, mutect2, varscan2
- TOPBP1 | c.750G>A p.K250= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as rs1338005805, COSV53433026, COSV99605096; called by muse, mutect2, varscan2
- TRIM14 | c.345C>T p.F115= | Silent (SNP) | VAF 15/95 reads (16%) | catalogued as COSV100419521; called by muse, mutect2, varscan2
- TTN | c.14607C>A p.T4869= (on ENST00000591111; = p.T3942= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 16/90 reads (18%) | catalogued as COSV100601991; called by muse, mutect2, varscan2
- ZNF136 | c.790C>T p.L264= | Silent (SNP) | VAF 25/76 reads (33%) | catalogued as COSV100677909; called by muse, mutect2, varscan2
- ZNF219 | c.45G>T p.P15= | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as COSV100070180; called by muse, varscan2
- ACOX1 | c.431-2798G>A | Intron (SNP) | VAF 6/28 reads (21%) | catalogued as rs372320683; called by muse, mutect2, varscan2
- DCAF12L1 | c.*1G>A | 3'UTR (SNP) | VAF 12/46 reads (26%) | catalogued as COSV100948177; called by muse, mutect2
- ERCC6 | c.1397+7764C>T | Intron (SNP) | VAF 8/37 reads (22%) | catalogued as COSV100875815; called by muse, mutect2, varscan2
- OR3A4P | n.872G>C | RNA (SNP) | VAF 26/129 reads (20%) | called by muse, mutect2, varscan2
- XIST | n.8231A>G | RNA (SNP) | VAF 6/24 reads (25%) | called by mutect2, varscan2
